TCGA case TCGA-2G-AAG0 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/251b5341-405f-4f16-8334-475f2d358c25

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 23 years; Year of birth: 1987; Vital status: Alive.

Diagnoses (4)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 23.8 years (8,687 days); Year of diagnosis: 2010; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,529 days (4.2 years); Ajcc serum tumor markers: S2; Sites of involvement: Rete Testis / Tunica Albuginea.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 92 days; Days to treatment end: 135 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Germ cell tumor, NOS: Tissue or organ of origin: Testis, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 18.9 years (6,904 days); Days to diagnosis: -1,783 days (-4.9 years); AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the testis (histology not recorded by GDC). Laterality: Bilateral; Age at diagnosis: 23.7 years (8,669 days); Days to diagnosis: -18 days.
4. Metastasis of diagnosis 1 (Mixed germ cell tumor), site: Lung, NOS. Age at diagnosis: 24.0 years (8,777 days); Days to diagnosis: 90 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 90 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 90 days.
- Days to follow up: 1,217 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,529 days (4.2 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -4: Lactate Dehydrogenase 329; Alpha Fetoprotein 11; Human Chorionic Gonadotropin 12.4.
- Day 23: Lactate Dehydrogenase 275; Alpha Fetoprotein 3; Human Chorionic Gonadotropin 1.6.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not achieve pregnancy following 12 or more months of unprotected intercourse; Risk factors: Undescended Testis; Undescended testis corrected: Yes; Undescended testis corrected age range: 3-9 years; Undescended testis corrected laterality: Right; Undescended testis corrected method: Orchiopexy; Undescended testis history: Yes; Undescended testis history laterality: Right.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Cousin; Relationship primary diagnosis: Testicular Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Testicular Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAG0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 220 mg.
  Slide TCGA-2G-AAG0-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAG0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAG0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History of undescended testis: Yes, right testicle only; Level of non descent: Inguinal; History hypospadias: No; History fertility: Did not achieve pregnancy following > or = 12 months of unprotected intercourse; Tumor status: Tumor free.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Bilateral diagnosis timing type: Metachronous; Testis tumor macroextent: Involves extratesticular structures: Tunica albuginea; Testis tumor microextent: Rete Testis; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 80.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor.
- Primary pathology, Histology list, Histology 3: Histologic diagnosis: Non-Seminoma, Teratoma (Mature).
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 329; Pre orchi hcg: 12.4; Pre orchi afp: 11.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 275; Post orchi hcg: 1.6; Post orchi afp: 3.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Testicle; Other malignancy histological type: Tgct; Days from index date to other malignancy diagnosis: -1780.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,529 days; disease-specific survival: no event (censored), 1,529 days; disease-free interval: event (new tumor event after initially disease-free), 90 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 90 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAG0-01A-11D-A42X-01): tumor purity 0.43, ploidy 2.86, whole-genome doublings 1.
